Gene-level copy-number profile of tumor specimen TCGA-EB-A5UM-01A from TCGA case TCGA-EB-A5UM, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 48.9 years (17,867 days).
Specimen TCGA-EB-A5UM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.41c62ca9-f9bf-45e6-bc2a-398f81ff57c0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EB-A5UM-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/26a48d80-f3a2-4810-821e-7637e678beb8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 6,799; copy number 2: 49,040; copy number 3: 1,669; copy number 4: 1,504; copy number 5: 277; copy number 6: 481; copy number 7: 25; copy number 9: 13.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EB-A5UM-01A-11D-A30W-01): tumor purity 0.72, ploidy 1.95, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 796 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:27,217,714–27,496,994, 2 genes, copy number 6: PURPL, AC113355.1.
- chr6:167,607–9,294,133, 181 genes, copy number 5 (broad region; genes not listed).
- chr6:10,747,759–10,930,423, 2 genes, copy number 6 (within-gene range 4–6): TMEM14B, AL024498.2.
- chr6:10,762,723–21,602,383, 154 genes, copy number 6 (broad region; genes not listed).
- chr6:21,822,536–21,822,737, 1 gene, copy number 6: AL136313.1.
- chr6:33,064,569–33,457,544, 43 genes, copy number 6: HLA-DPA1, HLA-DPB1, RPL32P1, HLA-DPA2, COL11A2P1, HLA-DPB2, HLA-DPA3, HCG24, COL11A2, RXRB, RNY4P10, SLC39A7, HSD17B8, MIR219A1, RING1, ZNF70P1, HTATSF1P1, AL645940.1, HCG25, VPS52, RPS18, B3GALT4, WDR46, MIR6873, PFDN6, MIR6834, RGL2, TAPBP, ZBTB22, DAXX, SMIM40, SMIM40, MYL8P, LYPLA2P1, RPL35AP4, KIFC1, RPL12P1, PHF1, CUTA, SYNGAP1, SYNGAP1-AS1, MIR5004, ZBTB9.
- chr6:37,507,348–38,154,624, 11 genes, copy number 6 (within-gene range 4–6): LINC02520, AL353597.2, AL353597.1, MIR4462, AL353597.3, MDGA1, AL121574.1, ZFAND3, RN7SL285P, RNVU1-33, AL589655.1.
- chr6:40,713,411–43,369,647, 96 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr6:44,342,650–50,521,104, 82 genes, copy number 6 (broad region; genes not listed).
- chr6:56,431,950–58,438,364, 30 genes, copy number 6: RCC2P7, DST, DST-AS1, RPL17P26, RNU6-626P, BEND6, OSTCP6, FTH1P15, MRPL30P1, KIAA1586, ZNF451, ZNF451-AS1, BAG2, RAB23, PRIM2, MIR548U, FO680682.1, AL021368.3, AL021368.5, AL021368.1, AL021368.2, GUSBP4, AL021368.4, POM121L14P, LINC00680, AL445250.1, GAPDHP15, AL390237.1, RBBP4P4, AL603755.1.
- chr6:77,650,274–77,927,028, 1 gene, copy number 6 (within-gene range 3–6): MEI4.
- chr20:13,995,369–16,053,197, 1 gene, copy number 5 (within-gene range 1–5): MACROD2.
- chr20:14,223,041–15,619,819, 14 genes, copy number 5: RN7SL864P, FLRT3, RNU6-228P, AL121582.1, RNF11P2, MACROD2-IT1, RPS10P2, MACROD2-AS1, AL138808.1, RNU6-1159P, RNU6-115P, RNA5SP475, AL121584.1, ENSAP1.
- chr20:17,209,060–17,226,146, 3 genes, copy number 5: RNU1-131P, AL359511.2, AL359511.3.
- chr20:31,257,664–32,743,567, 67 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr20:49,046,246–49,484,297, 14 genes, copy number 6: CSE1L, STAU1, ARPC3P1, DDX27, ZNFX1, ZFAS1, AL049766.2, SNORD12C, AL049766.1, SNORD12B, AL049766.3, SNORD12, KCNB1, AL035685.1.
- chr20:52,192,159–57,343,994, 76 genes, copy number 5–9 (within-gene range 4–9) (broad region; genes not listed).
- chr20:57,357,426–57,359,498, 2 genes, copy number 6: MTND1P9, MTRNR2L3.
- chr20:57,561,080–58,515,399, 16 genes, copy number 6: PCK1, AL035541.1, ZBP1, PMEPA1, NKILA, AL162291.1, AL354984.1, LINC01742, AL354984.2, AL354984.3, C20orf85, ANKRD60, PPP4R1L, RAB22A, VAPB, APCDD1L.

Autosomal genes at a single copy (total copy number 1): 6,799. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
